Somatic mutation profile of tumor specimen 0DNCOR from CCDI case PBCBBW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Spindle cell rhabdomyosarcoma; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 14.9 years (5,438 days).
Specimen 0DNCOR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c444db3-b7ab-43d6-b99a-5c43cae763c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNCH0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9cb0cb1-ac30-4990-84b3-ddc35cf1315b

The open-access MAF lists 45 somatic variants for this specimen: 30 protein-altering or splice-affecting, 8 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 8, Intron 6, Frame Shift Ins 4, Nonsense Mutation 2, In Frame Del 1, 5'UTR 1, Splice Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADRA1D | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 46/223 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1346709984, COSV65240349; called by muse, mutect2, varscan2
- CCNL1 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 165/958 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs774609871; called by muse, mutect2, varscan2
- ETAA1 | c.2353A>G p.T785A | Missense Mutation (SNP) | VAF 702/2316 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as rs1395355473; called by muse, mutect2
- IHO1 | c.1309C>T p.R437W | Missense Mutation (SNP) | VAF 150/454 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as rs372304968; called by muse, mutect2, varscan2
- LAD1 | c.926G>A p.R309K | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as COSV100943906; called by muse, mutect2
- MUC12 | c.2782C>A p.R928S (on ENST00000379442; = p.R785S on NM_001164462.1) | Missense Mutation (SNP) | VAF 51/190 reads (27%) | SIFT tolerated (0.88); PolyPhen benign (0.234); catalogued as rs776692875; called by muse, mutect2
- NKX2-8 | c.260G>C p.R87P | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs376874404, COSV51874326; called by muse, mutect2, varscan2
- OR1C1 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 214/1020 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68716294; called by muse, mutect2, varscan2
- SIN3A | c.1846C>T p.R616C | Missense Mutation (SNP) | VAF 150/620 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64582856; called by muse, mutect2, varscan2
- SLC17A1 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 296/1273 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs144651108, COSV55076933; called by muse, mutect2, varscan2
- TSKU | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 54/281 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs764170991; called by muse, mutect2, varscan2
- ZBTB32 | c.293G>C p.R98T | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV52889308, COSV52889886; called by muse, mutect2, varscan2
- ZFAT | c.3524C>G p.T1175R | Missense Mutation (SNP) | VAF 297/817 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.831); catalogued as rs181970358; called by muse, mutect2, varscan2
- ANGPTL2 | c.442_445dup p.R149Qfs*54 | Frame Shift Ins (INS) | VAF 86/397 reads (22%) | called by mutect2, pindel, varscan2
- IQGAP2 | c.4727G>T p.*1576Lext*20 | Nonstop Mutation (SNP) | VAF 223/1394 reads (16%) | called by muse, mutect2, varscan2
- MECR | c.479G>T p.S160I | Missense Mutation (SNP) | VAF 30/618 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.101); called by muse, mutect2
- MNT | c.648_649insCG p.G217Rfs*21 | Frame Shift Ins (INS) | VAF 52/386 reads (13%) | called by mutect2, pindel, varscan2
- NASP | c.264_266del p.F90del | In Frame Del (DEL) | VAF 218/1191 reads (18%) | called by pindel, varscan2
- NGLY1 | c.1605G>A p.W535* | Nonsense Mutation (SNP) | VAF 239/1480 reads (16%) | called by muse, mutect2, varscan2
- NUP210 | c.964C>A p.L322I | Missense Mutation (SNP) | VAF 100/569 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OLFM3 | c.467T>C p.L156S (on ENST00000338858 / NM_001288821.1; = p.L136S on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 281/1250 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PCDH11X | c.3550C>A p.H1184N | Missense Mutation (SNP) | VAF 224/521 reads (43%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHB1 | c.1385G>T p.R462L | Missense Mutation (SNP) | VAF 435/1135 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- PCDHGA6 | c.487G>T p.G163* | Nonsense Mutation (SNP) | VAF 158/752 reads (21%) | called by muse, mutect2, varscan2
- PLD2 | c.576T>G p.S192R | Missense Mutation (SNP) | VAF 189/530 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SIGLEC1 | c.1855_1856insA p.R619Qfs*72 | Frame Shift Ins (INS) | VAF 161/481 reads (33%) | called by mutect2, pindel, varscan2
- SLC24A1 | c.2849T>G p.M950R | Missense Mutation (SNP) | VAF 189/820 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- SNX2 | c.867_870dup p.A291Rfs*12 | Frame Shift Ins (INS) | VAF 599/1711 reads (35%) | called by mutect2, pindel, varscan2
- TES | c.650C>A p.A217E | Missense Mutation (SNP) | VAF 331/1255 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.24689-1G>T p.X8230_splice (on ENST00000591111; = p.X7303_splice on NM_133378.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 263/1608 reads (16%) | called by muse, mutect2, varscan2
- CLEC3B | c.375G>A p.V125= | Silent (SNP) | VAF 62/386 reads (16%) | called by muse, mutect2, varscan2
- CPAMD8 | c.1890C>T p.F630= (on ENST00000651564; = p.F583= on NM_015692.5) | Silent (SNP) | VAF 62/232 reads (27%) | catalogued as rs776271256, COSV52230579; called by muse, mutect2, varscan2
- GALR2 | c.138G>T p.V46= | Silent (SNP) | VAF 35/174 reads (20%) | called by muse, mutect2, varscan2
- GGTLC3 | c.639C>T p.A213= | Silent (SNP) | VAF 104/2581 reads (4%) | called by muse, mutect2
- GPATCH8 | c.285C>T p.T95= | Silent (SNP) | VAF 360/1892 reads (19%) | catalogued as rs374539559, COSV59193078; called by muse, mutect2, varscan2
- KRT6A | c.141G>C p.L47= | Silent (SNP) | VAF 89/585 reads (15%) | called by muse, mutect2, varscan2
- OR5M10 | c.582C>T p.V194= | Silent (SNP) | VAF 360/2086 reads (17%) | called by muse, mutect2, varscan2
- PDCD6IP | c.2019C>T p.G673= | Silent (SNP) | VAF 259/1643 reads (16%) | called by muse, mutect2, varscan2
- CEP152 | c.4093+73G>T | Intron (SNP) | VAF 51/696 reads (7%) | called by muse, mutect2
- DCK | c.91+17A>C | Intron (SNP) | VAF 39/347 reads (11%) | catalogued as rs756463162; called by muse, mutect2, varscan2
- IGSF9 | c.-43C>T | 5'UTR (SNP) | VAF 25/117 reads (21%) | catalogued as rs1270187244; called by muse, mutect2, varscan2
- MYO7B | c.6250-199C>A | Intron (SNP) | VAF 15/73 reads (21%) | called by muse, mutect2, varscan2
- RBFOX1 | c.220-101151C>A | Intron (SNP) | VAF 49/236 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.34523-148G>C | Intron (SNP) | VAF 362/2469 reads (15%) | catalogued as rs750023728; called by muse, mutect2, varscan2
- TTN | c.10360+4177C>A | Intron (SNP) | VAF 715/2265 reads (32%) | called by muse, mutect2, varscan2
